Surgical pathology report (de-identified scan), TCGA case TCGA-MT-A67D, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Minnesota, specimen TCGA-MT-A67D-01A (Primary Tumor).

[page 1 of 10]
study subject ID:

unique patient ID:

Tumor ID:

Collected:

Received:

Reported:

SPECIMEN(S):

A: Left lateral margin

B: Right lateral margin

C: Left anterior margin

D: Right posterior margin

E: Right anterior margin

F: Deep margin

G: Bone

H: Ventral side of tongue

I: Right composite resection, anterior floor of mouth/mandible

J: Sublingual gland, right

K: Level 1

L: Level 2A

M: Level 3

N: Level 4

O: Level 2B

ICD-O-3

Carcinoma, squamous cell -
keratinizing NOS 8071/3

Site Anterior floor of mouth
Q04.0

9/5/16/13

[page 2 of 10]
FINAL DIAGNOSIS:

I. Anterior floor of mouth/mandible, right, composite resection:

- Tumor type: Invasive squamous cell carcinoma, keratinizing type, moderately differentiated.

- Tumor site: anterior floor of mouth.

- Tumor size: 2.5 x 1.3 x 0.3 cm.

- Depth of invasion: 0.3 cm.

- Angiolymphatic invasion: Absent.

- Perineural invasion: Absent.

- Bone sections including bone margins free of involvement by tumor

- Status of margins: Free of tumor. The tumor is 0.5 cm from the closest margin (posterior); all other margins are approximately 1 cm or more from the tumor, plus separately submitted margins are all free of tumor

- Total lymph nodes : 23

- Number of lymph nodes involved: None (0/23)

- Stage pT2/N0/M0

A. Oral cavity, left lateral margin, excision (including AFS1)

- No evidence of malignancy.

B. Oral cavity, right lateral margin, excision (including BFS1)

- No evidence of malignancy.

[page 3 of 10]
C. Oral cavity, left anterior margin, excision (including CFS1)

- No evidence of malignancy

D. Oral cavity, right posterior margin, excision (including DFS1)

- No evidence of malignancy

E. Oral cavity, right anterior margin, excision (including EFS1)

- No evidence of malignancy

F. Oral cavity, deep margin, excision (including FFS1)

- No evidence of malignancy

G. Bone, biopsy

- Benign bone with no evidence of malignancy

H. Tongue, ventral side, excision (including HFS1)

- No evidence of malignancy

J. Sublingual gland, right, excision:

- Benign salivary gland tissue

K. Lymph nodes, level 1, neck dissection

- Two lymph nodes with no evidence of metastatic carcinoma (0/2)
- Unremarkable submandibular gland

[page 4 of 10]
L. Lymph nodes, level 2A, neck dissection

- Three lymph nodes with no evidence of metastatic carcinoma (0/3)

M. Lymph nodes, level 3, neck dissection

- Four lymph nodes with no evidence of metastatic carcinoma (0/4)

N. Lymph nodes, level 4, neck dissection

- Four lymph nodes with no evidence of metastatic carcinoma (0/4)

O. Lymph nodes, level 2B, neck dissection

- Ten lymph nodes with no evidence of metastatic carcinoma (0/10)

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

The patient is a -year-old man with squamous cell carcinoma of the floor of mouth. Operative procedure: Composite resection of anterior floor of mouth and mandible.

GROSS:

Received are fifteen fresh and formalin-fixed containers each labeled with the patient's name, and medical record number.

[page 5 of 10]
A. The first container is additionally labeled "A - left lateral margin." The specimen consists of a 1.7 x 0.9 x 0.5 cm tan-pink soft tissue fragment. The specimen is submitted intact for frozen section analysis as AFS1.

B. The second container is additionally labeled "B - right lateral margin." The specimen consists of a 6.2 x 0.5 x 0.3 cm tan-pink soft tissue fragment. The specimen is submitted intact for frozen section analysis as BFS1.

C. The third container is additionally labeled "C - left anterior margin." The specimen consists of a 4.1 x 0.5 x 0.3 cm tan-pink soft tissue fragment. The specimen is submitted intact for frozen section analysis as CFS1.

D. The fourth container is additionally labeled "Dj - right posterior margin." The specimen consists of a 1.5 x 0.5 x 0.3 cm tan-pink soft tissue fragment. The specimen is submitted intact for frozen section analysis as DFS1.

E. The fifth container is additionally labeled "E - right anterior margin." The specimen consists of a 3.2 x 0.7 x 0.3 cm tan-pink soft tissue fragment. The specimen is submitted intact for frozen section analysis as EFS1.

[page 6 of 10]
F. The sixth container is additionally labeled "F - deep margin." The specimen consists of a 0.9 x 0.6 x 0.3 cm red-tan soft tissue fragment. The specimen is submitted intact for frozen section analysis as FFS1.

G. The seventh container is additionally labeled "G - bone." The specimen consists of a 0.9 x 0.8 x 0.1 cm tan, bony fragment. The specimen is submitted intact following decalcification in a single cassette.

H. The eighth container is additionally labeled "H - ventral side of tongue." The specimen consists of a 1.7 x 0.7 x 0.3 cm tan-pink soft tissue fragment. The specimen is submitted intact for frozen section analysis as HFS1.

I. Specimen I is labeled "right composite resection anterior floor of mouth and mandible." The specimen consists of a segment of mandible with attached mucosa and soft tissue measuring 6.0 x 2.2 x 3.5 cm. The portion of mandibular bone measures 6.0 x 1.0 x 0.8 cm. The specimen is received oriented as follows: Two long - right, one long - left, two short - anterior. The specimen is inked as follows: Anterior - blue, posterior - green, left - yellow, right - red, deep - black. The mucosal surface is roughened, tan-purple, and a firm white lesion is identified which measures 2.5 x 1.3 cm on cross-section. The tumor is

[page 7 of 10]
located 1.1 cm from the right margin, 0.9 cm from the left margin, 3.0 cm from the deep margin and 0.5 cm from the posterior margin. The tumor invades to a depth of 0.3 cm upon sectioning. Soft tissue and mucosal margins are submitted and the specimen is placed in decalcification solution and the bony portion of the specimen will be submitted at a later date. Representative sections were procured for future studies on this specimen.

Summary of sections:

- I1 - anterior soft tissue margin, en face (blue).
- I2 - left soft tissue and mucosal margin , perpendicular (yellow).
- I3 - right soft tissue and mucosal margin, perpendicular (red).
- I4 - tumor with posterior (green) and deep (black) soft tissue margins.
- I5-I6 - additional tumor with posterior (green) soft tissue margin.
- I7- left mandibular margin, en face, and decal.
- I8 - right mandibular bone margin, en face, decal.
- I9-I10 - representative sections of mandible, decal.

J. The tenth container is additionally labeled "J - sublingual gland, right." The specimen consists of a single, partially membranous, tan, soft tissue mass measuring 2.5 x 1.4 x 1.1 cm in greatest dimension. The external surface displays a roughened area. The specimen is serially sectioned to reveal tan, lobulated cut surfaces. Distinct masses or lesions are not grossly identified. The entire specimen is submitted in three cassettes.

[page 8 of 10]
Summary of Sections:

J1-J3 - entire right sublingual gland.

K. The eleventh container is additionally labeled "K - level 1." The specimen consists of a 5.5 x 4.2 x 2.8 portion of tan-pink soft tissue. The tissue is dissected to reveal five potential lymph nodes ranging in size from 0.3 to 2.4 cm. Also identified is a possibly enlarged submandibular gland. The gland is serially sectioned to reveal to reveal pyramidal tan cut surfaces without masses or lesions identified. Representative sections are submitted.

Summary of Sections:

K1 - one potential lymph node, bisected, entirely submitted.

K2 - one potential lymph node, bisected, entirely submitted.

K3 - three potential lymph nodes, submitted intact.

K4 - representative submandibular gland.

L. The twelfth container is additionally labeled "L - level 2A." The specimen consists of a single unoriented portion of yellow-tan soft tissue measuring 4.9 x 2.1 x 1.5 cm in greatest dimension. The soft tissue is dissected to reveal five potential lymph nodes ranging in size from 0.3 to 2.2 cm in greatest dimension. Nodes are entirely submitted.

[page 9 of 10]
Summary of Sections:

L1 - one potential lymph node, bisected, entirely submitted.

L2 - four potential lymph nodes, submitted intact.

M. The thirteenth container is additionally labeled "M - level 3." The specimen consists of a single unoriented portion of yellow-tan, fibrofatty tissue measuring 6.1 x 4.1 x 0.9 cm in greatest dimension. The soft tissue is dissected to reveal three potential lymph nodes ranging in size from 0.3 to 2.5 cm in greatest dimension. Nodes are entirely submitted.

Summary of Sections:

M1 - one potential lymph node, bisected, entirely submitted.

M2 - two potential lymph nodes, submitted intact.

N. The fourteenth container is additionally labeled "N - level 4." The specimen consists of two irregular portions of yellow-tan soft tissue measuring 1.7 and 2.5 cm in greatest dimension. The fragments are submitted intact in two cassettes.

Summary of Sections:

N1-N2 - entire level 4.

O. The fifteenth container is additionally labeled "O - level 2B." The specimen consists of a single, unoriented yellow-tan portion

[page 10 of 10]
of fibrofatty soft tissue measuring 4.5 x 2.2 x 1.0 cm in greatest dimension. The soft tissue is dissected to reveal ten potential lymph nodes ranging in size from 0.3 to 1.6 cm in greatest dimension. The nodes are entirely submitted.

Summary of Sections:

O1 - one potential lymph node, bisected, entirely submitted.

O2 - four potential lymph nodes, submitted intact.

O3 - five potential lymph nodes, submitted intact.

MICROSCOPIC:

Microscopic examination is performed. Permanent sections confirm the frozen section diagnoses.

Source: NCI Genomic Data Commons file 947d527f-55e5-4c15-b9d3-099fad1f9d01 (TCGA-MT-A67D.BE777899-E5C2-4A08-8BBA-DBFC8042ACAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).